Somatic mutation profile of tumor specimen TARGET-40-NAAGJT-01A (aliquot TARGET-40-NAAGJT-01A-01D) from TARGET case TARGET-40-NAAGJT, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 21.3 years (7,763 days).
Specimen TARGET-40-NAAGJT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3d0bc65-0d8d-4848-b70b-f60aed9a0162.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJT-10B (Blood Derived Normal), aliquot TARGET-40-NAAGJT-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28a1118a-d459-4229-bd1e-e80695f690bd

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 4, Intron 4, Frame Shift Del 3, Splice Site 2, 3'UTR 2, Splice Region 1, RNA 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs199472796, CM097240; ClinVar: not provided / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARSF | c.1599G>C p.K533N | Missense Mutation (SNP) | VAF 110/176 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV63840573; called by muse, mutect2, varscan2
- C10orf120 | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV100271556, COSV61492526; called by muse, mutect2, varscan2
- CAGE1 | c.712C>G p.Q238E (on ENST00000512086; = p.Q102E on NM_205864.3) | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs747878969; called by muse, mutect2, varscan2
- CLYBL | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV59225679; called by muse, mutect2
- HTR1E | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV59509165; called by muse, mutect2, varscan2
- IL17RD | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs145766256; called by muse, mutect2, varscan2
- MAGEC3 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71610184; called by muse, mutect2, varscan2
- MUC16 | c.20750T>C p.M6917T | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as rs1404825309, COSV101200377; called by muse, mutect2, varscan2
- OR7G2 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59688755; called by muse, mutect2, varscan2
- OR8B2 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV66664162; called by muse, mutect2, varscan2
- PCDHGA12 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs775651426; called by muse, mutect2, varscan2
- PCLO | c.5266C>T p.R1756C | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1415697327, COSV61623247; called by muse, mutect2, varscan2
- PDE3A | c.1061A>G p.H354R | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.094); catalogued as rs1431791947; called by muse, mutect2, varscan2
- SLC17A6 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99582527; called by muse, mutect2, varscan2
- SVOP | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs1170390507, COSV54466088; called by muse, mutect2
- TLN2 | c.5491G>A p.A1831T | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs138052939; called by muse, varscan2
- ZNF208 | c.2891A>C p.K964T | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68114748; called by muse, mutect2, varscan2
- ALDH16A1 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKLE1 | c.1208C>T p.P403L (on ENST00000394458; = p.P349L on NM_152363.6) | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AQP3 | c.373+1G>A p.X125_splice | Splice Site (SNP) | VAF 38/528 reads (7%) | called by muse, mutect2
- B3GAT2 | c.886-8C>T | Splice Region (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- C6orf15 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); called by muse, mutect2
- CHD3 | c.2567A>T p.H856L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHRM5 | c.1396A>G p.T466A | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CNTNAP2 | c.3978A>C p.K1326N | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUL7 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 59/525 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- CUX1 | c.2723A>G p.N908S | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.031); called by muse, mutect2
- DGKG | c.911-1G>C p.X304_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- DLL3 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- DNAH14 | c.6157A>T p.K2053* (on ENST00000445597; = p.K2706* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- EDN1 | c.555C>A p.S185R | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ELOA3D | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 23/968 reads (2%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2
- FOXC1 | c.1481C>A p.A494D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- FOXP2 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FSBP | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GEMIN4 | c.2222C>G p.S741* | Nonsense Mutation (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- GLRA2 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR182 | c.961A>C p.N321H | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPSM2 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HMCN2 | c.5461A>G p.T1821A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.012); called by muse, mutect2
- HNRNPH1 | c.224_227del p.R75Kfs*22 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- INSM1 | c.815_838del p.C272_P279del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- MAP7D1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.112); called by muse, mutect2
- MED14 | c.1980G>T p.E660D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, mutect2
- MGAT2 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MKKS | c.1379C>G p.S460C | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MTMR2 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MUC12 | c.5354C>A p.T1785N (on ENST00000379442; = p.T1642N on NM_001164462.1) | Missense Mutation (SNP) | VAF 38/1000 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.413); called by muse, mutect2
- MUC17 | c.3638C>T p.T1213I | Missense Mutation (SNP) | VAF 38/571 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.07); called by muse, mutect2
- NKAIN3 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NUP133 | c.1530del p.N510Kfs*4 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- OR5B3 | c.770A>T p.Y257F | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR3D | c.1108_1112del p.T370Gfs*17 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- QSER1 | c.3152C>G p.S1051C (on ENST00000399302; = p.S1180C on NM_001076786.3) | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- RINT1 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SACS | c.12463A>C p.M4155L | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC45A3 | c.1636A>T p.S546C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2
- SPACA9 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- SPAG5 | c.2581G>C p.E861Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- TMEM200A | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS3 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 59/387 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTN | c.50515C>A p.P16839T (on ENST00000591111; = p.P9415T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBA8 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 16/379 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.319); called by muse, mutect2
- ZNF292 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- ABCA13 | c.11967T>A p.A3989= | Silent (SNP) | VAF 39/203 reads (19%) | called by muse, mutect2, varscan2
- AMDHD1 | c.201T>G p.T67= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- ASPM | c.7740A>G p.T2580= | Silent (SNP) | VAF 68/250 reads (27%) | catalogued as COSV99661149; called by muse, mutect2, varscan2
- CHD8 | c.7386C>T p.H2462= (on ENST00000646647 / NM_001170629.2; = p.H2183= on NM_020920.4) | Silent (SNP) | VAF 26/239 reads (11%) | called by muse, mutect2, varscan2
- CLIC5 | c.1188C>A p.I396= (on ENST00000185206 / NM_001370649.1; = p.I237= on NM_016929.5) | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV51755675; called by muse, mutect2, varscan2
- EPX | c.18C>G p.A6= | Silent (SNP) | VAF 26/206 reads (13%) | called by muse, mutect2, varscan2
- KARS1 | c.48G>A p.P16= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs767453488; called by muse, mutect2, varscan2
- MRGPRX2 | c.384C>T p.C128= | Silent (SNP) | VAF 34/192 reads (18%) | catalogued as rs200336580, COSV61674103; called by muse, mutect2, varscan2
- MUC16 | c.15687T>G p.S5229= | Silent (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- OR51V1 | c.879C>T p.I293= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs1390772318, COSV58315814; called by muse, mutect2, varscan2
- PEAK1 | c.189T>C p.P63= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- SLC6A5 | c.1177A>C p.R393= | Silent (SNP) | VAF 49/396 reads (12%) | called by muse, mutect2, varscan2
- TLR5 | c.1281C>T p.L427= | Silent (SNP) | VAF 28/231 reads (12%) | catalogued as COSV60558987; called by muse, mutect2, varscan2
- XK | c.117G>A p.L39= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- AC107023.1 | n.25+5473A>C | Intron (SNP) | VAF 12/67 reads (18%) | called by mutect2, varscan2
- CCT6A | c.-3G>C | 5'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- CD200R1 | c.68-16745G>T | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- DDX39A | c.*20C>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- GSTM2P1 | n.612G>C | RNA (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- LTA | c.*130G>A | 3'UTR (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65827G>A | Intron (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- SLC34A1 | c.1417-16G>A | Intron (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
